TARGET case TARGET-40-NAAEDB — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8d5d313b-df30-5e83-ae25-f99394f26d08

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 28 years; Vital status: Dead; Days to death: 1,249 days (3.4 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 28.5 years (10,427 days); Year of diagnosis: 2004; Metastasis at diagnosis: No Metastasis; Days to last follow up: 1,249 days (3.4 years).
   Pathology details: Necrosis percent: 23.
   Treatment given: Protocol identifier: GBCTTO/99.
   Treatment given: Therapeutic agents: Cisplatin.
   Treatment given: Therapeutic agents: Doxorubicin.
   Treatment given: Therapeutic agents: Ifosfamide.
   Treatment given: Therapeutic agents: Mesna.

Follow-up (3 entries)
- Days to follow up: 570 days (1.6 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 570 days (1.6 years).
- Days to follow up: 576 days (1.6 years); Days to first event: 576 days (1.6 years); First event: Relapse.
- Days to follow up: 1,249 days (3.4 years); Progression or recurrence: Yes; Progression or recurrence type: Local; Year of follow up: 2007.

Biospecimens (2 samples)
- Sample TARGET-40-NAAEDB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAEDB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAEDB-06A-01:
- Specimen Type: frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 70
- % Non Tumor Nuclei: Top from Biopsy: 30
- % Cellular Tumor: Top from Biopsy: 10
- % Normal: Top from Biopsy: 50
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 40
- % Tumor Nuclei: Bottom from Biopsy: 70
- % Non Tumor Nuclei: Bottom from Biopsy: 30
- % Cellular Tumor: Bottom from Biopsy: 10
- % Normal: Bottom from Biopsy: 50
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 40
- PASS/FAIL: fail

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAEDB-08A-01:
- Specimen Type: frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 0
- % Non Tumor Nuclei: Top from Biopsy: 100
- % Cellular Tumor: Top from Biopsy: 0
- % Normal: Top from Biopsy: 55
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 45*
- % Tumor Nuclei: Bottom from Biopsy: 1
- % Non Tumor Nuclei: Bottom from Biopsy: 100
- % Cellular Tumor: Bottom from Biopsy: 0
- % Normal: Bottom from Biopsy: 10
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 90*
- PASS/FAIL: fail

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1249
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Specific tumor region: Distal
- Definitive Surgery: Limb sparing
- Primary site progression: Yes
- Site of initial relapse: Lung
- Time to first relapse in days: 570
- Time to first enrollment on relapse protocol in days: 679
- Time to first SMN in days: 0
- Histologic response: Stage 1/2 (0-90 % necrosis)
- Relapse Type: Systemic, Locally recurrent
- Therapy: CDDP+ Doxo+ IFO +Mesna
